Surgical pathology report (de-identified scan), TCGA case TCGA-MQ-A4LI, project TCGA-MESO (Mesothelioma), tissue source site Washington University - NYU, specimen TCGA-MQ-A4LI-01A (Primary Tumor).

[page 1 of 2]
Result Type: Report
Result Date:
Result Status:
Result Title:
Performed by:

*** Final Report ***

ICD-0-3
Mesothelioma, epithelioid, NOS
9052/3
Site: pleura, NOS C38.4
hw
10/4/12

SPECIMEN DESCRIPTION
(NOTE)

(15) SLIDES (9) (2) (4)

SURGICAL PATHOLOGY REPORT

LOCATION:

PATHOLOGY NO.:

HOSPITAL NO.:
ACCOUNT NO.:
DATE RECEIVED:
DATE REPORTED:

PATIENT'S NAME:
AGE/SEX/DOB:
PHYSICIAN(S):
COPY TO:

DIAGNOSIS:

PLEURA, LEFT, BIOPSY:

A. MALIGNANT NEOPLASM WITH FEATURES CONSISTENT WITH MESOTHELIOMA (PLEASE SEE COMMENT).

B. LUNG, BRUSHING: BRONCHIAL EPITHELIAL CELLS WITH REACTIVE CHANGES. NEGATIVE FOR MALIGNANCY.

C. LUNG, WASHING: BRONCHIAL CELLS WITH REACTIVE CHANGES. NEGATIVE FOR MALIGNANCY.

COMMENT: The biopsy displays fragments of fibroadipose tissue and skeletal

Printed by:
Printed on:

Page 1 of 2
(Continued)

[page 2 of 2]
muscle infiltrated by a poorly differentiated neoplasm formed by epithelioid cells with high nuclear grade. The neoplastic cells are positive for S-100 while negative for carcinoembryonic antigen and Leu-M1 (as per immunohistochemistry performed at _____). Additionally, immunohistochemistry performed at _____ revealed that the malignant cells are strongly positive for keratin, while negative for carcinoembryonic antigen, B72.3, Ber-Ep4, and CD 15. Constellation of histological and immunohistochemical findings are those of a malignant mesothelioma.

=====

SPECIMEN: A (15) SLIDES (9) (2) (4)
(1) BLOCK

OPERATION:
PRE-OP DIAGNOSIS:
POST-OP DIAGNOSIS:
CLINICAL DATA:

GROSS DESCRIPTION: Received from _____ are 15 slides and 1
block as labeled above.

PATHOLOGIST: _____

Completed Action List:
* Perform by _____

Printed by: _____
Printed on: _____

IHPAA Discrepancy		☒

9/23/12 JW

Source: NCI Genomic Data Commons file 58dccd29-0031-4b2d-b4f6-6d2de1ba7988 (TCGA-MQ-A4LI.15AE69C3-52C2-4CD3-A1BD-6E4EAD5B6631.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).